Somatic mutation profile of tumor specimen TCGA-4T-AA8H-01A (aliquot TCGA-4T-AA8H-01A-11D-A40P-10) from TCGA case TCGA-4T-AA8H, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 42.4 years (15,494 days).
Specimen TCGA-4T-AA8H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67bf3648-1945-4dc1-b87c-07f3e615a3b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4T-AA8H-10B (Blood Derived Normal), aliquot TCGA-4T-AA8H-10B-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db97523f-9c7f-4245-b028-f595b2c77f82

The open-access MAF lists 135 somatic variants for this specimen: 106 protein-altering or splice-affecting, 28 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 28, Nonsense Mutation 8, Frame Shift Del 2, Splice Site 2, Splice Region 1, Frame Shift Ins 1, In Frame Del 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 105/174 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAK | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as rs753314164, COSV57564849; ClinVar: pathogenic; called by muse, mutect2
- ABCC12 | c.512C>A p.A171D | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as COSV100252435; called by muse, mutect2, varscan2
- ADAMTS4 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as COSV63487185; called by muse, mutect2, varscan2
- ADGRL4 | c.1450A>C p.N484H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV100875803; called by muse, mutect2
- ANKIB1 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.528); catalogued as rs755986517, COSV99728719; called by muse, mutect2, varscan2
- APC | c.2821G>T p.E941* | Nonsense Mutation (SNP) | VAF 31/126 reads (25%) | catalogued as CM105842, COSV57327519; called by muse, mutect2, varscan2
- APC | c.4466_4467dup p.H1490Yfs*18 | Frame Shift Ins (INS) | VAF 57/140 reads (41%) | catalogued as COSV57334014, COSV57343226, COSV57371310; called by mutect2, pindel, varscan2
- ATL1 | c.925A>G p.S309G | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV63295733; called by muse, mutect2, varscan2
- BTN2A2 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs775875965, COSV61857154; called by muse, mutect2, varscan2
- CAMTA1 | c.2461C>T p.L821F | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.12); catalogued as COSV100347986; called by muse, mutect2, varscan2
- CASQ2 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV99797275; called by muse, mutect2, varscan2
- CCDC174 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV99513672; called by muse, varscan2
- CDC20B | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99696708; called by muse, mutect2, varscan2
- CFAP58 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.294); catalogued as rs200619709, COSV57214177; called by muse, mutect2, varscan2
- CHAMP1 | c.1378_1380del p.P460del | In Frame Del (DEL) | VAF 30/208 reads (14%) | catalogued as rs782004732; called by mutect2, pindel, varscan2
- CLIP2 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.694); catalogued as rs200966015, COSV99791284; called by muse, mutect2, varscan2
- CREB1 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV62063548; called by muse, mutect2, varscan2
- CSMD3 | c.7639C>A p.L2547I (on ENST00000297405 / NM_001363185.1; = p.L2443I on NM_052900.3) | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.363); catalogued as COSV52113582; called by muse, mutect2, varscan2
- DEFB124 | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.012); catalogued as COSV100478770; called by muse, mutect2, varscan2
- DISP3 | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs561908282, COSV99608021; called by muse, mutect2, varscan2
- DOCK3 | c.5503C>A p.H1835N | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.023); catalogued as COSV99810550; called by muse, mutect2, varscan2
- EFHD1 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs761223584, COSV99898393; called by muse, mutect2, varscan2
- ESRP1 | c.1235T>C p.V412A | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64407482; called by muse, mutect2, varscan2
- FAM71C | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.74); catalogued as rs1232047752, COSV100175705; called by muse, mutect2, varscan2
- FAT2 | c.13001C>T p.S4334F | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99942251; called by muse, mutect2, varscan2
- FN1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs748170344, COSV100116729; called by muse, mutect2, varscan2
- FRAS1 | c.8972C>T p.T2991M | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376261766; called by muse, mutect2, varscan2
- FRMPD3 | c.3803G>A p.R1268Q | Missense Mutation (SNP) | VAF 164/316 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs1248741228, COSV52185844; called by muse, mutect2, varscan2
- FRMPD4 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.562); catalogued as COSV101042546; called by muse, varscan2
- GLCE | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs138637994, COSV55947145; called by muse, mutect2, varscan2
- HNRNPM | c.1231C>T p.L411F | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as COSV99725420; called by muse, mutect2, varscan2
- HYDIN | c.13643G>A p.R4548H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs1220556036, COSV66639790; called by muse, mutect2, varscan2
- IQGAP1 | c.3943G>A p.A1315T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV99184931; called by muse, mutect2, varscan2
- IQSEC2 | c.1835G>A p.R612H (on ENST00000642864 / NM_001111125.3; = p.R407H on NM_015075.2) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.266); catalogued as rs1556863232, COSV64723142; called by muse, mutect2, varscan2
- ISL1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100045222; called by muse, mutect2, varscan2
- ITCH | c.758C>T p.P253L (on ENST00000262650 / NM_001257137.3; = p.P212L on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.776); catalogued as rs540203213, COSV52929107, COSV99392426; called by muse, mutect2, varscan2
- ITGAV | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs554897868, COSV53708763; called by muse, mutect2, varscan2
- ITIH6 | c.3413C>T p.T1138I | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs866632624, COSV99513087; called by muse, mutect2, varscan2
- KANK3 | c.1489G>A p.A497T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV58358754; called by muse, mutect2, varscan2
- KCNH4 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs751569305, COSV52920746; called by muse, mutect2, varscan2
- KIF24 | c.3331C>T p.H1111Y | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.185); catalogued as rs1341619704, COSV99902998; called by muse, mutect2, varscan2
- KLHL34 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438276435, COSV101069902; called by muse, mutect2, varscan2
- LAMA4 | c.4493G>A p.R1498H (on ENST00000230538 / NM_001105206.3; = p.R1491H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as rs147556641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIFR | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs776173910, COSV54683796; called by muse, mutect2, varscan2
- LPCAT1 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs747860604, COSV52036505; called by muse, mutect2, varscan2
- LRRC15 | c.1193A>T p.N398I | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100752636; called by muse, mutect2, varscan2
- MAP2K2 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs531584619, COSV99502221; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARK1 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as COSV100857143; called by muse, mutect2, varscan2
- MIDN | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as rs746153442, COSV56295319; called by muse, mutect2, varscan2
- MRPL41 | c.156G>T p.Q52H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.67); catalogued as rs376218719; called by muse, mutect2, varscan2
- MYLK3 | c.728C>A p.P243H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV101189085; called by muse, mutect2, varscan2
- MYO7A | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101289092; called by muse, mutect2, varscan2
- NLRP2 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 26/160 reads (16%) | catalogued as rs1300799865, COSV54759322; called by muse, mutect2, varscan2
- NLRP8 | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs188779067, COSV52583273; called by muse, mutect2, varscan2
- NRBF2 | c.30+2T>G p.X10_splice | Splice Site (SNP) | VAF 13/62 reads (21%) | catalogued as COSV53258332; called by muse, mutect2, varscan2
- NSD3 | c.1451C>T p.T484M | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs147357661; called by muse, mutect2, varscan2
- OBSCN | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV52819406; called by muse, mutect2, varscan2
- OBSCN | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as rs768324296, COSV52746287; called by muse, mutect2, varscan2
- P3H1 | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs763655582, COSV52531398; called by muse, mutect2, varscan2
- PAQR9 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.009); catalogued as COSV100503752; called by muse, mutect2, varscan2
- PCDH15 | c.1127C>G p.P376R | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV57257698; called by muse, mutect2
- PCDH7 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 35/132 reads (27%) | catalogued as COSV62342899; called by muse, mutect2, varscan2
- PCID2 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99872384; called by muse, mutect2, varscan2
- PDE8B | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as rs750904456, COSV53740558; called by muse, mutect2, varscan2
- PDHA1 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.069); catalogued as COSV100134453; called by muse, mutect2, varscan2
- PLXNA4 | c.528C>A p.Y176* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV58102537; called by muse, mutect2, varscan2
- PLXNB2 | c.3428C>T p.T1143M | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs1443835685, COSV63780333; called by muse, varscan2
- POF1B | c.1054C>G p.L352V | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99426398; called by muse, mutect2, varscan2
- POLQ | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.115); catalogued as COSV51746046; called by muse, mutect2, varscan2
- POP4 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs547007300, COSV55676493; called by muse, mutect2, varscan2
- POTED | c.268T>C p.F90L | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as COSV100203074; called by muse, mutect2, varscan2
- PTCHD4 | c.1393C>A p.P465T | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as COSV100260507; called by muse, mutect2
- QSOX1 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100852840; called by muse, mutect2, varscan2
- RASEF | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs1028297274, COSV64585619; called by muse, mutect2, varscan2
- RHBDD1 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391540; called by muse, mutect2, varscan2
- RLBP1 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.937); catalogued as rs1238365040, COSV51527407; called by muse, mutect2, varscan2
- RPA4 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100232059; called by muse, mutect2
- SBF1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767703972, COSV100817622; called by muse, mutect2, varscan2
- SETX | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1237541645, COSV99809279; called by muse, mutect2, varscan2
- SLC16A14 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 117/241 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99725390; called by muse, mutect2, varscan2
- SLC26A3 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100385293, COSV60638429; called by muse, varscan2
- SLC7A4 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as rs148390805; called by muse, mutect2, varscan2
- SORBS2 | c.841C>T p.R281* (on ENST00000284776 / NM_021069.5; = p.R374* on NM_003603.6) | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as rs751096552, COSV53014020; called by muse, mutect2, varscan2
- SPANXN2 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100979861, COSV65129955; called by muse, mutect2, varscan2
- SPSB4 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV100141177; called by muse, mutect2
- SPTA1 | c.6025C>T p.R2009C | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs374336960, COSV63754955; called by muse, mutect2
- SPTA1 | c.5341G>A p.D1781N | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.113); catalogued as COSV100934668; called by muse, mutect2, varscan2
- SPTLC3 | c.459-1G>T p.X153_splice | Splice Site (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100983026; called by muse, mutect2, varscan2
- SYNE2 | c.11555C>T p.S3852L | Missense Mutation (SNP) | VAF 80/360 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100647247; called by muse, mutect2, varscan2
- TBC1D13 | c.314A>T p.N105I | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99804382; called by muse, mutect2, varscan2
- TENT5D | c.690G>T p.E230D | Missense Mutation (SNP) | VAF 71/301 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100382642; called by muse, mutect2, varscan2
- TRAT1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs138588985, COSV99849132; called by muse, mutect2, varscan2
- TRPV6 | c.2272G>A p.G758R | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.029); catalogued as rs757082631, COSV100844147; called by muse, mutect2, varscan2
- TTYH2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 31/152 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.343); catalogued as COSV99482925; called by muse, mutect2, varscan2
- TUBGCP5 | c.2795G>A p.R932K | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.475); catalogued as rs1474470455; called by muse, mutect2, varscan2
- USPL1 | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 11/159 reads (7%) | catalogued as COSV99687138; called by muse, mutect2
- VCX3A | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 37/311 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.108); catalogued as rs1273235273; called by muse, mutect2, varscan2
- ZBTB14 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100813431; called by muse, mutect2, varscan2
- ZNF304 | c.1250G>C p.R417T | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV99988527; called by muse, mutect2, varscan2
- ZNF518B | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | catalogued as rs1396218234, COSV100456671, COSV58725031; called by muse, mutect2, varscan2
- ZNF699 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.171); catalogued as COSV100426906; called by muse, mutect2, varscan2
- ZZZ3 | c.2161T>C p.Y721H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.804); catalogued as rs375472641; called by muse, mutect2, varscan2
- PIK3AP1 | c.1591_1592del p.P531Cfs*18 | Frame Shift Del (DEL) | VAF 24/101 reads (24%) | called by mutect2, pindel, varscan2
- PTGFR | c.49del p.L17Ffs*18 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- SCN1A | c.3430-6_3430-3del | Splice Region (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- ABCC3 | c.573G>A p.R191= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV53326604; called by muse, mutect2, varscan2
- ABCC4 | c.3879C>T p.F1293= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100972397; called by muse, mutect2, varscan2
- AFAP1 | c.448C>T p.L150= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs372896349; called by muse, mutect2, varscan2
- ARFGEF1 | c.5493A>G p.G1831= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as COSV99138245; called by muse, mutect2, varscan2
- ARHGEF16 | c.2004C>A p.G668= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs370789981, COSV65681215; called by muse, mutect2, varscan2
- BOC | c.3300G>C p.G1100= | Silent (SNP) | VAF 53/151 reads (35%) | catalogued as COSV99848436; called by muse, mutect2, varscan2
- CACNA1F | c.4365C>G p.G1455= | Silent (SNP) | VAF 59/195 reads (30%) | catalogued as COSV100544589, COSV100545594; called by muse, mutect2, varscan2
- CBLL2 | c.738C>T p.N246= | Silent (SNP) | VAF 58/196 reads (30%) | catalogued as COSV100081530; called by muse, mutect2, varscan2
- CEND1 | c.126G>A p.K42= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100204159; called by muse, mutect2, varscan2
- CPZ | c.1185C>T p.H395= (on ENST00000360986 / NM_001014447.3; = p.H384= on NM_003652.3) | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs961343700, COSV100248886; called by muse, mutect2, varscan2
- CREB3L2 | c.882C>T p.A294= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100381748; called by muse, mutect2, varscan2
- DMXL2 | c.1251G>A p.K417= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs572670667, COSV99196154; called by muse, mutect2, varscan2
- EZH1 | c.1572C>T p.C524= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as rs573197442, COSV70550145; called by muse, mutect2, varscan2
- FAM83H | c.3393C>T p.R1131= | Silent (SNP) | VAF 41/235 reads (17%) | catalogued as rs782491323, COSV62028497; called by muse, mutect2, varscan2
- FGF6 | c.75C>T p.L25= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs17183515; called by muse, mutect2, varscan2
- FKRP | c.477G>A p.P159= | Silent (SNP) | VAF 41/180 reads (23%) | catalogued as COSV59357913; called by muse, mutect2, varscan2
- IGHV1-3 | c.24C>G p.L8= | Silent (SNP) | VAF 117/476 reads (25%) | called by muse, mutect2, varscan2
- LZTS1 | c.1200G>A p.E400= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99742853; called by muse, mutect2
- MAP2 | c.4983G>T p.R1661= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV99559018; called by muse, mutect2, varscan2
- MTERF2 | c.1119A>G p.P373= | Silent (SNP) | VAF 11/155 reads (7%) | catalogued as COSV53526828; called by muse, mutect2
- NDC80 | c.792G>A p.K264= | Silent (SNP) | VAF 7/162 reads (4%) | catalogued as COSV99859552; called by muse, mutect2
- NOX1 | c.1629C>T p.C543= | Silent (SNP) | VAF 109/492 reads (22%) | catalogued as rs946595131, COSV99471523; called by muse, mutect2, varscan2
- PAK3 | c.804G>A p.E268= (on ENST00000262836 / NM_001324328.2; = p.E253= on NM_002578.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 78/340 reads (23%) | catalogued as rs746123616, COSV99456925; called by muse, mutect2, varscan2
- PCDHGC5 | c.2340G>A p.P780= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV99339136; called by muse, mutect2, varscan2
- PLEC | c.3846G>A p.T1282= (on ENST00000322810 / NM_201380.4; = p.T1172= on NM_000445.5) | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as rs556372016, COSV100512517; called by muse, mutect2, varscan2
- SSBP4 | c.948C>T p.A316= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as COSV99526016; called by muse, mutect2, varscan2
- SYT13 | c.288C>T p.N96= | Silent (SNP) | VAF 23/113 reads (20%) | catalogued as COSV99194672; called by muse, mutect2, varscan2
- XPNPEP2 | c.906C>A p.I302= | Silent (SNP) | VAF 72/280 reads (26%) | catalogued as rs375256196, COSV100941445, COSV64368421; called by muse, mutect2, varscan2
- L1CAM | chrX:153886970 C>T | 5'Flank (SNP) | VAF 66/282 reads (23%) | called by muse, varscan2
